Somatic mutation profile of tumor specimen ALCH-B2AS-TTP1-A (aliquot ALCH-B2AS-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2AS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 53.8 years (19,667 days).
Specimen ALCH-B2AS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 490dd89f-b74c-4a6f-922b-e4e4a82ab7ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2AS-NB1-A (Blood Derived Normal), aliquot ALCH-B2AS-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11c594bd-3ca9-4297-8733-9cf4ccb12738

The open-access MAF lists 155 somatic variants for this specimen: 110 protein-altering or splice-affecting, 25 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 25, Nonsense Mutation 9, Intron 8, 3'UTR 5, RNA 4, Nonstop Mutation 1, Splice Site 1, Frame Shift Ins 1, Translation Start Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CP | c.606dup p.D203Rfs*5 | Frame Shift Ins (INS) | VAF 15/153 reads (10%) | catalogued as rs386134143; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 22/204 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- AADAT | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1257462322; called by muse, mutect2
- ABCA13 | c.3731C>T p.S1244L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as COSV70027223; called by muse, mutect2
- AHNAK | c.14095G>T p.G4699C | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57203858; called by muse, mutect2
- ATP6V1B2 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99369327; called by muse, mutect2
- CBLIF | c.359G>A p.W120* | Nonsense Mutation (SNP) | VAF 33/303 reads (11%) | catalogued as rs1229526027; called by muse, mutect2, varscan2
- CCT8L2 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63462914; called by muse, mutect2
- CNR1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV62989573; called by muse, mutect2, varscan2
- CNTN4 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1330078093, COSV61876497; called by muse, mutect2, varscan2
- CSMD3 | c.7903C>T p.P2635S (on ENST00000297405 / NM_001363185.1; = p.P2531S on NM_052900.3) | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52099999, COSV52223769; called by muse, mutect2, varscan2
- DCSTAMP | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV52575994; called by muse, mutect2, varscan2
- DOCK6 | c.5116G>A p.V1706I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1414374197; called by muse, mutect2
- GRM5 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59629094; called by mutect2, varscan2
- HOXA1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV58029220; called by muse, mutect2, varscan2
- JPH2 | c.937C>A p.R313S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV65904077; called by muse, mutect2, varscan2
- KATNA1 | c.281A>C p.E94A | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV59504188; called by muse, mutect2, varscan2
- KCNE4 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs562524819; called by muse, mutect2
- KCNQ3 | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV66476739; called by muse, varscan2
- LRFN5 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 21/220 reads (10%) | catalogued as COSV53243425; called by muse, mutect2
- LRRD1 | c.832A>G p.S278G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1434097330, COSV58471832; called by muse, mutect2, varscan2
- NKX2-2 | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV65820309; called by muse, mutect2
- NRIP1 | c.1991G>A p.G664D | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs574552787; called by muse, mutect2, varscan2
- PDE8B | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV53748766; called by muse, mutect2, varscan2
- PKD1L1 | c.8200G>T p.G2734C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99221709; called by muse, mutect2, varscan2
- PLCL1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1236965488, COSV101407246; called by muse, mutect2, varscan2
- PPFIA4 | c.2404C>A p.Q802K (on ENST00000447715; = p.Q803K on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as rs867496412; called by muse, mutect2
- PPP2R3C | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1221696411; called by muse, mutect2
- SALL3 | c.2524G>A p.A842T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567563797; called by muse, mutect2, varscan2
- SESN3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV53583791; called by muse, mutect2
- SLC13A1 | c.1748C>A p.P583H | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521339; called by muse, mutect2
- SLC17A5 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1432042412; called by muse, mutect2, varscan2
- SLC24A2 | c.1167C>G p.I389M | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs760889415, COSV53862211; called by muse, mutect2, varscan2
- SNURF | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); catalogued as COSV57593868; called by muse, mutect2
- TECRL | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as COSV67090233; called by muse, mutect2, varscan2
- THBS2 | c.1381A>G p.I461V | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs776351721; called by muse, mutect2
- TNR | c.614C>G p.P205R | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54872398, COSV99686657; called by muse, mutect2
- TRPM2 | c.4342C>T p.H1448Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55970045; called by muse, mutect2, varscan2
- YARS1 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360212575; called by muse, mutect2, varscan2
- ZNF202 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV60248477; called by muse, mutect2
- ZNF518A | c.2554A>G p.T852A | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1554885196; called by muse, mutect2, varscan2
- ZNF571 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | catalogued as COSV60734562; called by muse, mutect2
- ZNF808 | c.1664C>G p.A555G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV63119663; called by muse, mutect2, varscan2
- ADGRB1 | c.2142G>C p.Q714H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- ADIPOR1 | c.742T>C p.S248P | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- AGAP3 | c.2591C>T p.P864L (on ENST00000622464; = p.P900L on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AMPH | c.36C>A p.N12K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ARHGEF40 | c.495C>A p.C165* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- ARPP21 | c.2159A>T p.Y720F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BAZ2A | c.5616C>G p.F1872L | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- BMP10 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C12orf40 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- C5 | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- CATSPER4 | c.771C>G p.C257W | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC93 | c.156+2T>G p.X52_splice | Splice Site (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- CDH19 | c.296T>C p.I99T | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- CHRFAM7A | c.713C>G p.P238R | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CPS1 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CSN3 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- CTDP1 | c.1017G>C p.Q339H | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- CYP3A5 | c.122C>G p.P41R | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP4F2 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2
- CYP4F22 | c.1143T>A p.D381E | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DNAH17 | c.11513T>A p.M3838K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DNAH9 | c.11045C>G p.A3682G | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- EHBP1 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); called by muse, mutect2
- FAAH | c.879C>G p.C293W | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- FAM102B | c.971A>G p.E324G | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCRL3 | c.2203T>A p.*735Kext*41 | Nonstop Mutation (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- GAREM1 | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSDME | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2
- KIAA2026 | c.4600C>T p.P1534S | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LGALS2 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2
- LILRB4 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- LTN1 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- MAGEB1 | c.77A>T p.K26M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); called by muse, varscan2
- MINDY4 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MUC15 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC16 | c.14576C>A p.S4859Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NAV3 | c.5805G>T p.Q1935H (on ENST00000397909 / NM_001024383.2; = p.Q1913H on NM_014903.6) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- NLRP12 | c.3167A>T p.Y1056F | Missense Mutation (SNP) | VAF 29/347 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.205); called by muse, mutect2
- NRK | c.3814C>G p.L1272V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OLFML2B | c.1421C>A p.P474H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- OTOG | c.3512A>T p.K1171M | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- PAQR9 | c.182C>A p.S61* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- PDIA3 | c.736C>G p.H246D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- PHEX | c.542C>A p.S181* | Nonsense Mutation (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- PLS1 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- PLXDC1 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PPME1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PRKCG | c.2024A>T p.Y675F | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRD | c.2974G>A p.V992I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, varscan2
- RETNLB | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- RGPD3 | c.4024C>T p.P1342S | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RSPH4A | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4C | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- SLC13A1 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC14A1 | c.1080C>A p.Y360* | Nonsense Mutation (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- SLC3A1 | c.1892G>T p.S631I | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SLITRK3 | c.1897A>G p.I633V | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMOD1 | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TOP3B | c.1690G>T p.V564L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- TTN | c.94646T>A p.L31549Q (on ENST00000591111; = p.L24125Q on NM_003319.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TYRP1 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP43 | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2
- WASF3 | c.39G>T p.L13F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- WFDC2 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- ZFYVE19 | c.730C>T p.P244S (on ENST00000355341 / NM_001077268.2; = p.P234S on NM_032850.5) | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); called by muse, mutect2
- ZSCAN5B | c.897C>G p.S299R | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); called by muse, mutect2
- ARHGAP4 | c.84G>A p.L28= | Silent (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- FAT3 | c.9366G>A p.E3122= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as rs753065708, COSV53116965; called by muse, mutect2
- FLNA | c.1911G>A p.P637= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs782428502, COSV61043764; called by muse, mutect2, varscan2
- GABRG1 | c.1305C>A p.R435= | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as COSV54958638; called by muse, mutect2
- GBA | c.1062C>T p.D354= | Silent (SNP) | VAF 36/318 reads (11%) | catalogued as CM110540; called by muse, mutect2, varscan2
- HOXD4 | c.318C>G p.P106= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- HTR3C | c.372C>T p.D124= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2727G>T p.R909= (on ENST00000286628 / NM_001161352.2; = p.R851= on NM_002247.4) | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as rs1344394851; called by muse, varscan2
- MYO7B | c.4416C>A p.S1472= | Silent (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
- NOTO | c.546G>T p.V182= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- OCRL | c.2523A>T p.A841= | Silent (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- OR2J2 | c.828C>G p.A276= | Silent (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- PAQR9 | c.987A>G p.V329= | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- PPFIA4 | c.2403C>A p.T801= (on ENST00000447715; = p.T802= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- PRG4 | c.2691T>A p.G897= | Silent (SNP) | VAF 29/262 reads (11%) | called by muse, mutect2, varscan2
- RAX2 | c.96C>T p.T32= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- RYR2 | c.12210G>T p.A4070= | Silent (SNP) | VAF 21/178 reads (12%) | catalogued as COSV100770553, COSV63685969, COSV63686121; called by muse, mutect2, varscan2
- SCN11A | c.2199A>G p.P733= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1239938360; called by muse, mutect2, varscan2
- SHOX | c.594C>A p.P198= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV100479135; called by muse, mutect2, varscan2
- SLC26A4 | c.969C>T p.Y323= | Silent (SNP) | VAF 26/286 reads (9%) | catalogued as rs748164675; called by muse, mutect2
- ST18 | c.2283C>A p.A761= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- ST18 | c.582T>C p.S194= | Silent (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- TP53 | c.816G>A p.V272= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as rs756421198, COSV52918960, COSV53313340, COSV53438396; called by muse, mutect2
- ZNF729 | c.2526T>C p.H842= | Silent (SNP) | VAF 20/346 reads (6%) | called by muse, mutect2
- ZNF81 | c.1929T>C p.C643= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- ACIN1 | c.2298-1884G>A | Intron (SNP) | VAF 14/140 reads (10%) | catalogued as rs1213203664; called by muse, mutect2, varscan2
- C16orf87 | c.346+1491G>A | Intron (SNP) | VAF 7/161 reads (4%) | called by muse, mutect2
- CDC42BPG | c.2731+12C>T | Intron (SNP) | VAF 10/49 reads (20%) | called by muse, varscan2
- ETNPPL | c.56+459T>G | Intron (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- FAM172BP | n.826G>C | RNA (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- IGLV10-54 | c.-10A>C | 5'UTR (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- LINC02756 | n.311+7340G>T | Intron (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- MARCHF1 | c.242+747A>G | Intron (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- NUDT4 | chr12:93377509 C>T | 5'Flank (SNP) | VAF 9/221 reads (4%) | catalogued as rs1040583212; called by muse, mutect2
- OR2A13P | n.546T>C | RNA (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- PPP4R1L | n.1938C>T | RNA (SNP) | VAF 6/31 reads (19%) | catalogued as rs1043305673; called by muse, mutect2
- SLA | c.-40-24C>T | Intron (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2
- SLC17A2 | c.*47T>C | 3'UTR (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- SMARCB1 | c.658-44G>T | Intron (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- SSPOP | n.11521G>A | RNA (SNP) | VAF 10/67 reads (15%) | catalogued as rs1380152530; called by muse, mutect2, varscan2
- STAT3 | c.*10A>G | 3'UTR (SNP) | VAF 20/181 reads (11%) | called by muse, mutect2
- TNS3 | c.*2185A>T | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- TNS3 | c.*2184G>T | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- TOX2 | c.*58G>T | 3'UTR (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- ZNF625 | chr19:12142654 C>A | 3'Flank (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2, varscan2
